Gene-level copy-number profile of tumor specimen ALCH-B0AQ-TTP1-A from ALCHEMIST case ALCH-B0AQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.6 years (21,418 days).
Specimen ALCH-B0AQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f1f7e733-d7e3-4123-be21-3a1501bcf1a0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0AQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/7842dbc5-14f1-480c-8c1a-7b5b396bcd3e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 1,013; copy number 2: 55,951; copy number 3: 1,283; copy number 4: 109; copy number 5: 14; copy number 6: 4; copy number 7: 6; copy number 8: 1; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:223,947,605–223,950,416, 1 gene: CICP5.
- chr4:151,027,090–151,027,617, 1 gene: AK4P6.
- chr5:100,388,853–100,389,938, 1 gene: AC113385.2.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr10:35,219,894–35,231,394, 2 genes: LINC02634, RNU6-794P.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.
- chr15:41,828,095–41,848,155, 2 genes (within-gene range 0–2): JMJD7-PLA2G4B, PLA2G4B.
- chr16:15,104,312–15,131,601, 2 genes (within-gene range 0–2): NPIPP1, PKD1P6-NPIPP1.
- chr17:47,450,568–47,492,492, 1 gene: MRPL45P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 7 (within-gene range 2–7): TTC34, AC242022.2, AC242022.1.
- chr1:150,698,060–150,720,895, 2 genes, copy number 5: HORMAD1, RNU6-1042P.
- chr5:135,802,985–135,803,075, 1 gene, copy number 7: MIR5692C1.
- chr7:7,066,964–7,067,045, 1 gene, copy number 8: MIR3683.
- chr8:7,256,904–7,298,024, 6 genes, copy number 5: FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P, FAM90A20P.
- chr9:65,189,995–65,250,826, 4 genes, copy number 6: BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1.
- chr11:48,880,111–48,908,946, 4 genes, copy number 5: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr16:10,718,633–10,720,015, 2 genes, copy number 7 (within-gene range 2–7): MTCYBP33, MTND6P33.
- chr16:32,475,051–32,478,250, 1 gene, copy number 5: ABCD1P3.
- chr21:44,133,610–44,210,114, 1 gene, copy number 9 (within-gene range 2–9): GATD3A.

Autosomal genes at a single copy (total copy number 1): 852. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
